Somatic mutation profile of tumor specimen MMRF_2190_1_BM_CD138pos (aliquot MMRF_2190_1_BM_CD138pos_T1_KHS5U_L08707) from MMRF case MMRF_2190, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 54.9 years (20,067 days).
Specimen MMRF_2190_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a66731f-00bc-4f21-b825-d152d8f3b3e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2190_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2190_1_PB_Whole_C2_KHS5U_L08706; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9695bb71-360a-407a-9ec6-f541ae665030

The open-access MAF lists 133 somatic variants for this specimen: 46 protein-altering or splice-affecting, 18 silent, 69 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, 3'UTR 35, Silent 18, Intron 18, 5'UTR 10, Nonsense Mutation 4, RNA 2, 5'Flank 2, 3'Flank 2, Splice Site 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 16/224 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705661, COSV66706270; called by muse, mutect2
- KRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 25/97 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 46/347 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- B3GAT1 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 46/171 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.695); catalogued as COSV56999956; called by muse, varscan2
- C10orf120 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 114/248 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as rs772291761, COSV100271761; called by muse, mutect2, varscan2
- EFTUD2 | c.2189G>A p.R730H | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as COSV53655180; called by muse, mutect2, varscan2
- FAM186A | c.7007G>A p.R2336Q | Missense Mutation (SNP) | VAF 62/136 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs1223115458; called by muse, mutect2, varscan2
- GALC | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs370117160, CM960676; called by muse, mutect2, varscan2
- IGHV2-70 | c.287A>T p.K96I | Missense Mutation (SNP) | VAF 80/86 reads (93%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs138836314; called by muse, varscan2
- OR3A1 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 41/214 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372689671; called by muse, mutect2, varscan2
- PLEKHG6 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1418710643, COSV99164027; called by muse, mutect2, varscan2
- PLIN4 | c.1811C>T p.T604I (on ENST00000301286; = p.T619I on NM_001367868.2) | Missense Mutation (SNP) | VAF 146/308 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.215); catalogued as rs1357567930; called by muse, mutect2, varscan2
- SLC6A3 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 151/305 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs751595931, COSV54368468; called by muse, mutect2, varscan2
- STK40 | c.115C>G p.P39A | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV63736549; called by muse, mutect2, varscan2
- TTN | c.56005C>T p.R18669C (on ENST00000591111; = p.R11245C on NM_003319.4) | Missense Mutation (SNP) | VAF 75/248 reads (30%) | PolyPhen probably damaging (0.998); catalogued as rs200898955; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- WWC3 | c.2792C>T p.T931M | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1211298163; called by muse, mutect2, varscan2
- ZP4 | c.391G>C p.D131H | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV100850531; called by muse, mutect2, varscan2
- ADAMTS18 | c.2068A>C p.N690H | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.212); called by muse, varscan2
- ASTN2 | c.1708T>G p.Y570D (on ENST00000313400 / NM_001365069.1; = p.Y519D on NM_014010.5) | Missense Mutation (SNP) | VAF 80/155 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- CPXCR1 | c.749T>C p.I250T | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- EVPL | c.5100C>G p.Y1700* | Nonsense Mutation (SNP) | VAF 65/358 reads (18%) | called by muse, mutect2, varscan2
- FCER2 | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 44/112 reads (39%) | called by muse, mutect2, varscan2
- FZD2 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- IRAG2 | c.3079A>G p.R1027G (on ENST00000636465; = p.R72G on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 211/505 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.011); called by muse, varscan2
- KISS1R | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.28); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- LRRIQ1 | c.4157A>G p.E1386G | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MUC5B | c.16736C>T p.A5579V | Missense Mutation (SNP) | VAF 33/211 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- NUP42 | c.8T>A p.I3N | Missense Mutation (SNP) | VAF 178/357 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- OPCML | c.358_361del p.D120Ifs*10 | Frame Shift Del (DEL) | VAF 32/177 reads (18%) | called by pindel, varscan2
- PRKD2 | c.1685T>G p.F562C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PTBP1 | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 59/410 reads (14%) | called by muse, mutect2, varscan2
- RAD51AP1 | c.1049_1051del p.T350del (on ENST00000228843 / NM_001130862.2; = p.T333del on NM_006479.5) | In Frame Del (DEL) | VAF 80/512 reads (16%) | called by mutect2, pindel, varscan2
- RXFP1 | c.1861A>T p.K621* | Nonsense Mutation (SNP) | VAF 7/112 reads (6%) | called by muse, mutect2
- S100Z | c.256T>C p.C86R | Missense Mutation (SNP) | VAF 38/232 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SI | c.1887+2T>C p.X629_splice | Splice Site (SNP) | VAF 32/179 reads (18%) | called by muse, mutect2, varscan2
- SLC10A6 | c.375C>T p.L125= | Splice Region (SNP) | VAF 61/137 reads (45%) | called by muse, mutect2, varscan2
- SLC38A2 | c.1459A>T p.T487S | Missense Mutation (SNP) | VAF 73/293 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- SLC40A1 | c.871C>A p.P291T | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT tolerated (0.55); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- SLIT3 | c.2423A>G p.Y808C | Missense Mutation (SNP) | VAF 56/222 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SYNDIG1L | c.266C>G p.T89R | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- TIAM1 | c.3947G>A p.G1316E | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- TKTL1 | c.1652C>G p.S551C | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.928); called by muse, mutect2
- TP63 | c.636G>T p.Q212H | Missense Mutation (SNP) | VAF 88/327 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TSPAN7 | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 45/351 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- UBP1 | c.577T>C p.F193L | Missense Mutation (SNP) | VAF 109/226 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- WDFY3 | c.5362C>G p.L1788V | Missense Mutation (SNP) | VAF 56/104 reads (54%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- ADCK5 | c.1077G>T p.S359= | Silent (SNP) | VAF 29/153 reads (19%) | catalogued as COSV58233831; called by muse, mutect2, varscan2
- AHDC1 | c.1660C>T p.L554= | Silent (SNP) | VAF 50/171 reads (29%) | called by muse, mutect2, varscan2
- BPIFB1 | c.261G>A p.L87= | Silent (SNP) | VAF 44/146 reads (30%) | called by muse, mutect2, varscan2
- DDX10 | c.1149C>T p.A383= | Silent (SNP) | VAF 43/258 reads (17%) | catalogued as rs767002502; called by muse, mutect2, varscan2
- EIPR1 | c.864C>G p.V288= | Silent (SNP) | VAF 119/250 reads (48%) | catalogued as COSV66130987; called by muse, mutect2, varscan2
- FETUB | c.684C>T p.S228= | Silent (SNP) | VAF 25/197 reads (13%) | catalogued as rs747298078; called by muse, mutect2, varscan2
- GDF10 | c.870A>G p.R290= | Silent (SNP) | VAF 26/82 reads (32%) | called by muse, mutect2, varscan2
- GPR88 | c.735C>T p.A245= | Silent (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2, varscan2
- IGKV1-5 | c.321T>A p.T107= | Silent (SNP) | VAF 48/49 reads (98%) | catalogued as rs369955682; called by muse, mutect2
- MUC16 | c.32946T>C p.P10982= | Silent (SNP) | VAF 68/238 reads (29%) | called by muse, mutect2, varscan2
- NUTM2G | c.519G>A p.G173= | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as rs994662973, COSV100672629; called by muse, mutect2, varscan2
- PNISR | c.996T>C p.Y332= | Silent (SNP) | VAF 51/109 reads (47%) | called by muse, mutect2, varscan2
- PRX | c.1647G>A p.P549= | Silent (SNP) | VAF 124/264 reads (47%) | catalogued as rs202113722, COSV52527803, COSV52528592; called by muse, mutect2, varscan2
- PTPN12 | c.2217T>C p.C739= | Silent (SNP) | VAF 29/267 reads (11%) | called by muse, mutect2, varscan2
- SOWAHD | c.825G>C p.T275= | Silent (SNP) | VAF 8/169 reads (5%) | called by muse, mutect2
- TDRD9 | c.2538C>T p.S846= | Silent (SNP) | VAF 111/368 reads (30%) | catalogued as rs140463535, COSV100175349; called by muse, mutect2, varscan2
- USP31 | c.1752T>C p.R584= | Silent (SNP) | VAF 34/122 reads (28%) | catalogued as rs747267929; called by muse, mutect2, varscan2
- XBP1 | c.486T>C p.A162= | Silent (SNP) | VAF 21/52 reads (40%) | called by muse, mutect2
- AC093155.3 | c.*832dup | 3'UTR (INS) | VAF 13/88 reads (15%) | catalogued as rs35118015; called by mutect2, pindel, varscan2
- AC104825.1 | n.1582C>G | RNA (SNP) | VAF 95/302 reads (31%) | called by muse, mutect2, varscan2
- ACAD8 | c.*136T>A | 3'UTR (SNP) | VAF 16/157 reads (10%) | called by muse, mutect2, varscan2
- AICDA | c.*1543G>T | 3'UTR (SNP) | VAF 16/76 reads (21%) | called by muse, mutect2, varscan2
- ANKLE2 | c.181+2820C>T | Intron (SNP) | VAF 18/178 reads (10%) | called by muse, varscan2
- ARGLU1 | c.*665del | 3'UTR (DEL) | VAF 31/145 reads (21%) | called by mutect2, pindel, varscan2
- ASIC2 | c.556-180952A>T | Intron (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021040 T>A | 5'Flank (SNP) | VAF 92/226 reads (41%) | catalogued as rs532073995, COSV104379272; called by muse, mutect2, varscan2
- BICDL2 | chr16:3036023 T>A | 5'Flank (SNP) | VAF 14/70 reads (20%) | called by muse, mutect2
- CCDC57 | c.2241+928C>A | Intron (SNP) | VAF 140/446 reads (31%) | called by muse, mutect2, varscan2
- CLDN16 | c.*1947C>T | 3'UTR (SNP) | VAF 37/110 reads (34%) | called by muse, mutect2, varscan2
- DAGLA | c.*2110G>T | 3'UTR (SNP) | VAF 87/283 reads (31%) | called by muse, mutect2, varscan2
- DMD | c.31+83201G>A | Intron (SNP) | VAF 12/308 reads (4%) | called by muse, mutect2
- DPH7 | c.*113C>G | 3'UTR (SNP) | VAF 29/115 reads (25%) | catalogued as rs910691695; called by muse, mutect2, varscan2
- DTNB | c.1880-101C>T | Intron (SNP) | VAF 9/284 reads (3%) | called by muse, mutect2
- EIF5B | c.*1234A>G | 3'UTR (SNP) | VAF 22/140 reads (16%) | called by muse, mutect2, varscan2
- ERCC6 | c.*14C>G | 3'UTR (SNP) | VAF 42/235 reads (18%) | called by muse, mutect2, varscan2
- FUT4 | c.*2210A>G | 3'UTR (SNP) | VAF 13/85 reads (15%) | called by muse, mutect2, varscan2
- GABRG3 | c.-1C>T | 5'UTR (SNP) | VAF 9/66 reads (14%) | catalogued as rs926595024; called by muse, mutect2, varscan2
- GABRR1 | c.*1183A>C | 3'UTR (SNP) | VAF 11/71 reads (15%) | called by muse, mutect2, varscan2
- GCK | c.-24C>T | 5'UTR (SNP) | VAF 38/231 reads (16%) | called by muse, mutect2, varscan2
- GPC5 | c.1561+345229T>C | Intron (SNP) | VAF 19/66 reads (29%) | called by muse, mutect2, varscan2
- HBE1 | c.-267+102420del | Intron (DEL) | VAF 85/402 reads (21%) | called by pindel, varscan2
- HDAC6 | c.1994+27T>G | Intron (SNP) | VAF 23/51 reads (45%) | called by muse, mutect2, varscan2
- IFT27 | c.174+197G>T | Intron (SNP) | VAF 14/69 reads (20%) | called by muse, mutect2
- IFT27 | c.174+129G>T | Intron (SNP) | VAF 38/207 reads (18%) | called by muse, mutect2, varscan2
- IFT27 | c.174+22G>C | Intron (SNP) | VAF 72/424 reads (17%) | called by muse, mutect2, varscan2
- IFT27 | c.35-114A>G | Intron (SNP) | VAF 24/111 reads (22%) | called by muse, varscan2
- JDP2 | chr14:75472418 G>A | 3'Flank (SNP) | VAF 77/177 reads (44%) | called by muse, mutect2, varscan2
- KCNK10 | c.*1659C>T | 3'UTR (SNP) | VAF 51/95 reads (54%) | catalogued as rs185960468; called by muse, mutect2, varscan2
- KLF2 | c.-61del | 5'UTR (DEL) | VAF 9/87 reads (10%) | called by mutect2, pindel, varscan2
- LURAP1L | c.-581G>A | 5'UTR (SNP) | VAF 52/101 reads (51%) | called by muse, mutect2, varscan2
- LZTS2 | c.-558T>C | 5'UTR (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- MAP4 | c.292+2990T>G | Intron (SNP) | VAF 10/150 reads (7%) | called by muse, mutect2
- MECP2 | c.*4590A>C | 3'UTR (SNP) | VAF 72/139 reads (52%) | called by muse, mutect2, varscan2
- MOB1B | c.*779T>C | 3'UTR (SNP) | VAF 71/142 reads (50%) | catalogued as rs1380854271; called by muse, mutect2, varscan2
- NRARP | c.*1094A>G | 3'UTR (SNP) | VAF 9/69 reads (13%) | called by muse, mutect2, varscan2
- NRXN1 | c.*2675G>C | 3'UTR (SNP) | VAF 25/129 reads (19%) | called by muse, mutect2, varscan2
- NRXN3 | c.3262+139A>T | Intron (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2
- NRXN3 | chr14:79864018 del T | 3'Flank (DEL) | VAF 16/118 reads (14%) | called by mutect2, pindel, varscan2
- OCA2 | c.-18G>T | 5'UTR (SNP) | VAF 99/303 reads (33%) | called by muse, mutect2, varscan2
- PAXIP1 | c.3058-11C>G | Intron (SNP) | VAF 70/284 reads (25%) | called by muse, mutect2, varscan2
- PCDHB4 | c.-29G>C | 5'UTR (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2, varscan2
- PCMTD1 | c.*2634C>G | 3'UTR (SNP) | VAF 37/264 reads (14%) | called by muse, mutect2, varscan2
- PLEKHO1 | c.-128G>C | 5'UTR (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2, varscan2
- PLXNA1 | c.*3191G>A | 3'UTR (SNP) | VAF 47/177 reads (27%) | catalogued as rs546392351; called by muse, varscan2
- PPP1R3D | c.*1541G>T | 3'UTR (SNP) | VAF 88/174 reads (51%) | called by muse, mutect2, varscan2
- PTBP2 | c.*1089T>C | 3'UTR (SNP) | VAF 18/91 reads (20%) | called by muse, mutect2, varscan2
- RASAL2 | c.*3336C>A | 3'UTR (SNP) | VAF 53/104 reads (51%) | called by muse, mutect2, varscan2
- RBM17 | c.*130A>T | 3'UTR (SNP) | VAF 11/24 reads (46%) | called by muse, mutect2, varscan2
- RBM17 | c.*273A>T | 3'UTR (SNP) | VAF 42/105 reads (40%) | catalogued as rs1320865269; called by muse, varscan2
- RBM17 | c.*403A>C | 3'UTR (SNP) | VAF 46/87 reads (53%) | called by muse, varscan2
- RNF125 | c.*3477T>C | 3'UTR (SNP) | VAF 37/102 reads (36%) | called by muse, mutect2, varscan2
- RPL36A | c.301-49del | Intron (DEL) | VAF 190/576 reads (33%) | called by pindel, varscan2
- RTN4 | c.3013+14748T>G | Intron (SNP) | VAF 17/183 reads (9%) | called by muse, mutect2
- SEMA5A | c.*413G>C | 3'UTR (SNP) | VAF 15/60 reads (25%) | called by muse, mutect2, varscan2
- SLC7A2 | c.*4610C>T | 3'UTR (SNP) | VAF 20/78 reads (26%) | called by muse, mutect2
- SLCO2B1 | c.-225G>C | 5'UTR (SNP) | VAF 7/76 reads (9%) | called by muse, mutect2
- SSX2IP | c.*249G>C | 3'UTR (SNP) | VAF 20/84 reads (24%) | called by muse, mutect2, varscan2
- STK39 | c.*287T>C | 3'UTR (SNP) | VAF 56/181 reads (31%) | called by muse, mutect2, varscan2
- TCERG1L | c.*586G>A | 3'UTR (SNP) | VAF 79/176 reads (45%) | catalogued as rs542997117, COSV64058880; called by muse, mutect2, varscan2
- TCHH | c.*259A>T | 3'UTR (SNP) | VAF 35/176 reads (20%) | catalogued as rs536719010; called by muse, varscan2
- TENM1 | c.*3237A>G | 3'UTR (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- TRAF3 | c.*1904A>G | 3'UTR (SNP) | VAF 25/155 reads (16%) | catalogued as rs1260633214; called by muse, mutect2, varscan2
- UBTFL2 | n.339C>T | RNA (SNP) | VAF 43/603 reads (7%) | called by muse, mutect2
- XIAP | c.*6018C>T | 3'UTR (SNP) | VAF 22/161 reads (14%) | catalogued as rs1402537779; called by muse, mutect2, varscan2
- YTHDC1 | c.-148G>A | 5'UTR (SNP) | VAF 152/346 reads (44%) | called by muse, mutect2, varscan2
- ZNF462 | c.6832+634G>A | Intron (SNP) | VAF 29/116 reads (25%) | called by muse, mutect2, varscan2
- ZNF572 | c.*1528_*1531del | 3'UTR (DEL) | VAF 15/95 reads (16%) | catalogued as rs959431026; called by mutect2, pindel, varscan2
